Gene-level copy-number profile of tumor specimen TCGA-A6-2671-01A from TCGA case TCGA-A6-2671, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 85.8 years (31,329 days).
Specimen TCGA-A6-2671-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.77d8c735-b271-4b13-affa-8f15a60e1860.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-2671-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/368298ba-cc70-4422-bde2-de8f1745b4b2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 703; copy number 2: 16,614; copy number 3: 12,946; copy number 4: 21,549; copy number 5: 2,192; copy number 6: 1,126; copy number 7: 3,569; copy number 8: 920; copy number 9: 195.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-2671-01A-01D-1549-01): tumor purity 0.73, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 195 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,996,754–39,105,445, 1 gene, copy number 9 (within-gene range 2–9): ADAM9.
- chr8:39,106,990–46,638,886, 109 genes, copy number 9 (broad region; genes not listed).
- chr9:17,906,563–21,937,651, 82 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr9:21,811,621–21,893,857, 3 genes, copy number 9: TUBB8P1, AL359922.2, AL359922.3.

Autosomal genes at a single copy (total copy number 1): 702. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
